Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6498, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6498-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. PROSTATE
- B. PROSTATE MARGIN

SPECIMEN(S):

- A. PROSTATE
- B. PROSTATE MARGIN

GROSS DESCRIPTION:

A. PROSTATE

Received fresh labeled with matching patient identifiers is a resected prostate gland weighing 48 g and measuring 4.5-cm from right to left, 4.8-cm from anterior to posterior, and 3.5-cm from apex to base. The external capsule is red, smooth and intact. The apex and base are removed from the specimen yielding a new weight of 23 g. The specimen is serially sectioned from apex to base. Cut section shows firm, tan fibrous parenchyma. No lesions or nodules are grossly appreciated. The right and left seminal vesicle measure 2.3 x 1.5 x 0.5, and 2.9 x 1.7 x 0.5 cm respectively. Both are bisected show beige tan cystic tissue. The right and left vas measure 3.1 x 0.2, and 1.9 x 0.2 cm, respectively. Both are sectioned to show firm tan tube structure. A portion of the specimen is submitted for tissue procurement. The remainder is entirely submitted for microscopic evaluation. Cassettes are submitted as follows:

- A1-A2: Right apex
- A3: Left Apex
- A4: Level 1 right anterior
- A5: Level 1 right posterior
- A6: Level 1 left anterior
- A7: Level 1 left posterior
- A8: Level 2 capsule, right side
- A9: Level 2 capsule, left side
- A10-A11: Right lateral base
- A12: Right base
- A13-A14: Right base with proximal urethral margin
- A15-A16: Left base with proximal urethral margin
- A17-A18: Left base
- A19-A20: Left lateral base
- A21: Right seminal vesicle, right vas
- A22: Left seminal vesicle, left vas

B. PROSTATE MARGIN

Received in formalin in a container labeled with matching patient identifiers is a fragment of pink tan unoriented soft tissue measuring 0.7 x 0.3 x 0.1 cm. The entire specimen is submitted in cassette B1.

DIAGNOSIS:

A. PROSTATE, PROSTATECTOMY:

- PROSTATIC ADENOCARCINOMA, GLEASON SCORE 3 + 4 = 7.
- TUMOR INVOLVES RIGHT AND LEFT LOBES AND ~ 15% OF THE PROSTATE.
- TUMOR IS PRESENT AT THE INKED RIGHT APICAL AND RIGHT ANTERIOR MARGINS, WITH PERIPROSTATIC FAT INVOLVEMENT.
- BILATERAL SEMINAL VESICLES AND BLADDER BASE, NO TUMOR SEEN.

B. PROSTATE MARGIN, EXCISION:

- PROSTATIC TISSUE, NO TUMOR SEEN.

SYNOPTIC REPORT - PROSTATE GLAND

Location: right and left lobes from apex to mid

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 15%

Gleason Grade/Sum:: Grade 3 + 4 , Sum 7

High Grade PIN Present: No

Perineural Invasion: Yes

[page 2 of 2]
[REDACTED]

Vascular/Lymphatic Invasion: No
Seminal Vesicle Invasion: No
Periprostatic Fat Involved: Yes
Details: right apex and right anterior
Bladder Neck Involved: No
Margins Involvement: Yes
Location: see above
Linear Distance: Diffuse (>10mm or Multifocal)
Frozen Performed: No
Lymph Nodes: Negative
Other Pathologic Findings: BPH
Pathological Staging (pTNM): T 3a N X M X

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer

[REDACTED]

Source: NCI Genomic Data Commons file 4868a49b-2aa0-4789-a2e8-ed6ae095b915 (TCGA-G9-6498.0F610D96-54E9-4E40-B3D4-19554C782057.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).